Surgical pathology report (de-identified scan), TCGA case TCGA-WC-A881, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-A881-01A (Primary Tumor).

Accession:

Specimen Date/Time:

ICD O-3
Melanoma, spindle cell NOS
Site @ Choroid C69.3
8772/3
QW 1/14/14

DIAGNOSIS

(A) LEFT GLOBE:

(> 90%)

CHOROIDAL MELANOMA, SPINDLE TYPE, 18 MM BASE.
Vortex veins, negative for tumor.
Optic nerve, negative for tumor.
Scleral invasion: absent
(SEE COMMENT)

COMMENT

A PAS is reviewed which highlights internal structures. Mitotic count is less than 1 per 10 high-power fields.

GROSS DESCRIPTION

(A) LEFT GLOBE – An intact left eye (23 x 22 x 21 mm) has an attached optic nerve (10 mm in length). The scleral area shows a fresh mark from prior FNA by surgeon. Extraocular lesions are not identified. The anterior chamber is clear formed by a 10 mm brown iris and shows a round 4.0 mm pupil. A large shadow is present on transillumination corresponding to a dark brown-black pigmented mass arising in the choroidal region from 12-6 o'clock with an 18.0 mm base x 12.0 mm height, 6.0 mm from the optic nerve and does not involve the ciliary body. The sclera beneath the tumor is grossly intact.

SECTION CODE: A1-A4, vortex vein (superior nasal, superior temporal, inferior temporal, inferior nasal); A5, pupil-nerve sections; A6, A7, calottes also with tumor.

CLINICAL HISTORY

Uveal melanoma.

SNOMED CODES

T-AA000, M-87203

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have no

Entire report and diagnosis completed by:

-----END OF REPORT-----

OK

Source: NCI Genomic Data Commons file 9b10ebec-fb41-4076-b4be-2cfa51834038 (TCGA-WC-A881.6D728871-8D6D-47B7-8A29-66870CA78A91.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).